Gene-level copy-number profile of tumor specimen ALCH-AEQE-TTP1-A from ALCHEMIST case ALCH-AEQE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,248 days).
Specimen ALCH-AEQE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f1b6d6e-e078-4ee2-b019-9b134b939dfc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEQE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/8e16ebd6-05b1-4297-9303-38cf85b68374

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 58; copy number 2: 55,519; copy number 3: 2,547; copy number 4: 201; copy number 5: 69.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,173,141–1,816,048, 23 genes, copy number 5: CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6.
- chr5:12,553,890–12,574,637, 1 gene, copy number 5: AC106771.1.
- chr5:25,701,217–25,716,715, 2 genes, copy number 5: RNU6-374P, AC022418.1.
- chr5:26,669,346–26,749,997, 5 genes, copy number 5: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1.
- chr7:21,900,899–21,945,903, 1 gene, copy number 5 (within-gene range 3–5): CDCA7L.
- chr8:124,550,784–126,329,538, 28 genes, copy number 5 (within-gene range 4–5): MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1.
- chr8:138,588,235–138,914,041, 1 gene, copy number 5: COL22A1.
- chr8:141,968,091–141,968,841, 1 gene, copy number 5: AC104417.1.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
